MMRF case MMRF_2511 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d64025cb-a2e5-4e06-a7c0-36876c355e92

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.8 years (23,289 days); Days to last known disease status: 616 days (1.7 years); Days to last follow up: 616 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Third line of therapy; Days to treatment start: 391 days (1.1 years); Days to treatment end: 391 days (1.1 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 393 days (1.1 years); Days to treatment end: 393 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 1): M Protein 3.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Hemoglobin 8.74 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 10.9 g/dL; Glucose 5.28 mmol/L.
- Day 85 (ECOG 1): M Protein 2.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 33.5 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 152 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.15 mmol/L; Albumin 29 g/L; Total Protein 8.6 g/dL; Glucose 5.39 mmol/L.
- Day 141: Hemoglobin 7.5 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 153 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.23 mmol/L; Albumin 29 g/L; Total Protein 8.5 g/dL; Glucose 6.93 mmol/L.
- Day 266 (ECOG 1): M Protein 1.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 23.4 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.71 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.18 mmol/L; Albumin 31 g/L; Total Protein 8 g/dL; Glucose 6.88 mmol/L.
- Day 410: M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 19.5 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.67 g/L; Beta 2 Microglobulin 2.45 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 0.5 ×10⁹/L; Platelets 14 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.2 mmol/L; Albumin 30 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 519: M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.5 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 1.25 g/L; Hemoglobin 8 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL; Glucose 6.33 mmol/L.
- Day 616: Hemoglobin 8.12 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.18 mmol/L; Albumin 31 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -9: Weight: 77 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2511_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2511_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
